CCDI case PBCCEF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Oropharynx.
https://portal.gdc.cancer.gov/cases/2012acfc-bec3-48a0-bc5e-40fc08c9e0e6

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Mixed type rhabdomyosarcoma: ICD-O-3 morphology code: 8902/3; Tissue or organ of origin: Oropharynx, NOS; Age at diagnosis: 5.8 years (2,129 days).

Biospecimens (3 samples)
- Sample 0DOJUT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOJW2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DOJY4: Tissue type: Tumor; Specimen type: Solid Tissue.
